Gene-level copy-number profile of tumor specimen TARGET-20-PARIZR-09A from TARGET case TARGET-20-PARIZR, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,695 days).
Specimen TARGET-20-PARIZR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.4126642f-c415-55c3-bf95-e90358ff4aed.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARIZR-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 387 have no estimate.
https://portal.gdc.cancer.gov/files/f135705c-e709-4ef4-8264-c7715568bb84

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,932; copy number 1: 858; copy number 2: 55,984; copy number 3: 392; copy number 6: 70.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:31,399,784–31,478,936, 6 genes: MICA, AL645933.3, Y_RNA, LINC01149, AL645933.1, HCP5.
- chr12:131,596,857–131,597,115, 1 gene: AC140063.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 70 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 6 (within-gene range 2–6): AC244205.1.
- chr2:88,857,161–89,986,702, 69 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
